Somatic mutation profile of tumor specimen RC-B6SQ-TTP1-A (aliquot RC-B6SQ-TTP1-A-1-1-D-A94K-47) from RC case RC-B6SQ, project RC-PTCL: Refractory Cancers (RC) - Peripheral T-Cell Lymphoma (PTCL). Sex at birth: female; Vital status: Alive; Primary diagnosis: Angioimmunoblastic T-cell lymphoma; Tissue or organ of origin: Lymph nodes of multiple regions; Age at diagnosis: 53.7 years (19,606 days).
Specimen RC-B6SQ-TTP1-A: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0e93e279-0030-4d02-aa75-a9bcce4724ef.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen RC-B6SQ-NB1-A (Peripheral Whole Blood; tissue type Normal), aliquot RC-B6SQ-NB1-A-1-0-D-A94K-47; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3ed01d22-1721-4219-a266-cdd4d5bdb381

The open-access MAF lists 37 somatic variants for this specimen: 30 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 27, Silent 7, Frame Shift Del 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS20 | c.5326T>C p.Y1776H | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT tolerated (0.53); PolyPhen benign (0.315); catalogued as rs1242310838; called by muse, mutect2
- ARHGAP44 | c.796C>T p.R266W | Missense Mutation (SNP) | VAF 48/201 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762885019, COSV99310087; called by muse, mutect2, varscan2
- FBXO46 | c.1582G>A p.D528N | Missense Mutation (SNP) | VAF 87/334 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58349591; called by muse, mutect2, varscan2
- FLT4 | c.2872G>A p.G958R | Missense Mutation (SNP) | VAF 82/319 reads (26%) | SIFT tolerated (0.78); PolyPhen benign (0.005); catalogued as rs766043774, COSV56105768; called by muse, mutect2, varscan2
- KRTAP13-1 | c.331G>A p.G111S | Missense Mutation (SNP) | VAF 43/178 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.101); catalogued as rs375873361; called by muse, mutect2, varscan2
- NF1 | c.3722G>A p.R1241Q | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs543387071, CM153416, COSV62192087, COSV62222414; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NRCAM | c.2558G>A p.R853H (on ENST00000379028 / NM_001371124.1; = p.R837H on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/170 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs557294509; called by muse, mutect2
- PLAGL1 | c.653C>T p.T218I | Missense Mutation (SNP) | VAF 57/207 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.024); catalogued as rs1414195613; called by muse, mutect2, varscan2
- SEPTIN8 | c.767G>A p.R256Q | Missense Mutation (SNP) | VAF 21/157 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1163672316, COSV51523422; called by muse, mutect2, varscan2
- TET2 | c.3825del p.L1276Wfs*87 | Frame Shift Del (DEL) | VAF 41/81 reads (51%) | catalogued as rs1163049631, COSV54396254; called by mutect2, pindel, varscan2
- ZNF75D | c.184G>A p.G62R | Missense Mutation (SNP) | VAF 29/321 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as rs370618867, COSV66132596; called by muse, mutect2
- ABL2 | c.2996G>A p.C999Y (on ENST00000502732 / NM_007314.4; = p.C984Y on NM_005158.5) | Missense Mutation (SNP) | VAF 53/236 reads (22%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.341); called by muse, mutect2, varscan2
- ANO8 | c.2858del p.S953Tfs*24 | Frame Shift Del (DEL) | VAF 75/298 reads (25%) | called by mutect2, varscan2
- CD300C | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 105/402 reads (26%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.568); called by muse, mutect2, varscan2
- CYP4F12 | c.880A>T p.K294* | Nonsense Mutation (SNP) | VAF 46/192 reads (24%) | called by muse, mutect2, varscan2
- DMD | c.3718C>T p.L1240F | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- DNM1 | c.1328C>T p.T443I | Missense Mutation (SNP) | VAF 38/171 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.399); called by muse, mutect2, varscan2
- G3BP1 | c.223A>G p.T75A | Missense Mutation (SNP) | VAF 26/126 reads (21%) | SIFT tolerated (0.32); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GRM1 | c.3541T>C p.S1181P | Missense Mutation (SNP) | VAF 25/157 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- MPRIP | c.1720C>G p.P574A | Missense Mutation (SNP) | VAF 57/234 reads (24%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2, varscan2
- MYO5B | c.4316C>T p.A1439V | Missense Mutation (SNP) | VAF 51/186 reads (27%) | SIFT tolerated (0.51); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NR3C1 | c.1214C>T p.P405L | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.054); called by mutect2, varscan2
- PCDHGA11 | c.2024A>T p.D675V | Missense Mutation (SNP) | VAF 100/415 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- PCSK5 | c.2597T>A p.M866K | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- PLA2G4A | c.797T>G p.L266R | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- PSME4 | c.3036A>C p.L1012F | Missense Mutation (SNP) | VAF 25/114 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SPATA46 | c.38C>G p.P13R | Missense Mutation (SNP) | VAF 57/199 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SSH2 | c.1525G>A p.E509K | Missense Mutation (SNP) | VAF 51/207 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.395); called by muse, mutect2, varscan2
- TMEM104 | c.169T>G p.F57V | Missense Mutation (SNP) | VAF 43/192 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.486); called by muse, mutect2, varscan2
- TRIML1 | c.586C>A p.Q196K | Missense Mutation (SNP) | VAF 67/212 reads (32%) | SIFT tolerated (0.41); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- DAG1 | c.930C>T p.V310= | Silent (SNP) | VAF 129/335 reads (39%) | called by muse, mutect2, varscan2
- LRRC71 | c.381C>A p.T127= | Silent (SNP) | VAF 55/210 reads (26%) | called by muse, mutect2, varscan2
- LY9 | c.1659C>T p.H553= | Silent (SNP) | VAF 30/158 reads (19%) | called by muse, mutect2, varscan2
- MED12L | c.5100G>T p.V1700= | Silent (SNP) | VAF 26/112 reads (23%) | called by muse, mutect2, varscan2
- PTP4A3 | c.378C>T p.Y126= | Silent (SNP) | VAF 71/241 reads (29%) | catalogued as rs1202954787; called by muse, mutect2, varscan2
- RFESD | c.369A>T p.T123= | Silent (SNP) | VAF 43/193 reads (22%) | catalogued as COSV57224939; called by muse, mutect2, varscan2
- TPRG1L | c.111G>A p.G37= | Silent (SNP) | VAF 63/217 reads (29%) | called by muse, mutect2, varscan2
